CCDI case PBCDGP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3d05d69e-dff9-4109-9b65-ca955f3f0479

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Ganglioglioma, NOS: ICD-O-3 morphology code: 9505/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.8 years (4,685 days).

Biospecimens (3 samples)
- Sample 0DPDHB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPDHK: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPDI1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
